Somatic mutation profile of tumor specimen C3L-02118-01 (aliquot CPT0109300010) from CPTAC case C3L-02118, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,832 days).
Specimen C3L-02118-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbf9316e-95b0-41ef-8035-d1170c3e511a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02118-31 (Blood Derived Normal), aliquot CPT0109340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/353df540-2b85-42df-ac97-2284d9bf6f51

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Intron 3, Nonsense Mutation 2, RNA 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/208 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 29/236 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- C6orf15 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1298952152; called by muse, mutect2, varscan2
- COL15A1 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV66646717; called by muse, mutect2
- DCAF4L1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1427420580; called by muse, mutect2
- ESPNL | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs751081371, COSV99615679; called by muse, mutect2, varscan2
- KIF15 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375650379; called by muse, mutect2
- MORC2 | c.698C>T p.T233M (on ENST00000397641 / NM_001303256.3; = p.T171M on NM_014941.3) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.894); catalogued as rs924468105; called by muse, mutect2, varscan2
- MROH9 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs766660390, COSV63012034; called by muse, mutect2, varscan2
- NACC1 | c.1217T>C p.F406S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); catalogued as rs531044891; called by muse, mutect2, varscan2
- NMBR | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs745523807; called by muse, mutect2
- OR8K5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376114385, COSV100537278; called by muse, mutect2, varscan2
- PRAMEF20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1234445065; called by muse, mutect2
- SLITRK1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs765288417, COSV65676362; called by muse, mutect2, varscan2
- SRCIN1 | c.2059C>T p.H687Y (on ENST00000621492; = p.H653Y on NM_025248.3) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1323310056; called by muse, mutect2, varscan2
- SSX7 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV53340677; called by muse, mutect2
- SYNJ2 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 29/186 reads (16%) | catalogued as rs201799213; called by muse, mutect2, varscan2
- TSSK4 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV104383239; called by muse, mutect2
- CDHR1 | c.348G>A p.L116= | Splice Region (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2, varscan2
- DUSP6 | c.820_821insTC p.E274Vfs*7 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | called by mutect2, pindel*
- ESRRB | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- FAM20B | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2
- IRX2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- LEP | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRRN3 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2
- MCRIP2 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- POPDC2 | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PRAMEF5 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SHROOM3 | c.5816A>G p.D1939G | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TARS2 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZC3H12B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- FAM214A | c.900A>G p.L300= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs200513144; called by muse, mutect2
- SLC6A15 | c.102T>C p.F34= | Silent (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- SND1 | c.276G>A p.G92= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs1341158474; called by muse, mutect2
- SOX30 | c.1263C>T p.S421= | Silent (SNP) | VAF 42/236 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.1026G>A p.A342= | Silent (SNP) | VAF 25/259 reads (10%) | catalogued as rs776068574, COSV66164008; called by muse, mutect2
- WNT7B | c.324C>T p.Y108= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs375198790; called by muse, mutect2, varscan2
- ADAMTS2 | c.1629+1054C>A | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- LINC00452 | n.845G>A | RNA (SNP) | VAF 14/78 reads (18%) | catalogued as rs1456165682; called by mutect2, varscan2
- MYH16 | n.4472G>A | RNA (SNP) | VAF 17/176 reads (10%) | catalogued as rs777991094; called by muse, mutect2
- NKAIN3 | c.472-55160G>A | Intron (SNP) | VAF 30/135 reads (22%) | catalogued as rs1270151755, COSV100132401; called by mutect2, varscan2
- RRM2B | c.48+98T>C | Intron (SNP) | VAF 32/283 reads (11%) | called by muse, mutect2, varscan2
